Somatic mutation profile of tumor specimen TARGET-20-PATAKZ-09A (aliquot TARGET-20-PATAKZ-09A-01D) from TARGET case TARGET-20-PATAKZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.2 years (3,368 days).
Specimen TARGET-20-PATAKZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28105526-3ad7-4842-b8ee-b8d901d97bec.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATAKZ-14A (Bone Marrow Normal), aliquot TARGET-20-PATAKZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7f0557a-cf5d-4f59-83cf-53e92c915511

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX15 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61028395; called by muse, mutect2, varscan2
- GATA2 | c.953C>G p.A318G | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV62003120, COSV62003236, COSV62003503; called by muse, varscan2
- GATA2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV62003359; called by muse, varscan2
- EP300 | c.3631del p.E1211Rfs*16 | Frame Shift Del (DEL) | VAF 28/296 reads (9%) | called by mutect2, pindel
- GATA2 | c.954C>T p.A318= | Silent (SNP) | VAF 10/91 reads (11%) | called by muse, varscan2
